Somatic mutation profile of tumor specimen TCGA-GL-8500-01A (aliquot TCGA-GL-8500-01A-11D-2396-08) from TCGA case TCGA-GL-8500, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.9 years (23,338 days).
Specimen TCGA-GL-8500-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a56d8aa-ab99-41cf-9f8c-c33c060b79cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-8500-10A (Blood Derived Normal), aliquot TCGA-GL-8500-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bab6b85b-1437-4a85-8ebd-3fab29e81f75

The open-access MAF lists 89 somatic variants for this specimen: 72 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Frame Shift Del 9, Nonsense Mutation 3, Frame Shift Ins 3, Splice Region 3, In Frame Del 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.1985T>C p.L662P | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54693181; called by muse, mutect2, varscan2
- ABHD10 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753223588, COSV56324497; called by muse, mutect2, varscan2
- ANXA11 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55415135; called by muse, mutect2, varscan2
- ARHGEF28 | c.4247T>A p.I1416N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV55247914; called by muse, mutect2, varscan2
- CACNA1A | c.5149C>T p.Q1717* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV64190436; called by muse, mutect2, varscan2
- CHRNA1 | c.143T>A p.V48D | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.088); catalogued as COSV53681722; called by muse, mutect2, varscan2
- CLPTM1L | c.1148T>A p.F383Y | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as COSV57989460; called by muse, mutect2, varscan2
- CUL4A | c.2134C>G p.H712D (on ENST00000375440 / NM_001008895.4; = p.H612D on NM_003589.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58371362; called by muse, mutect2, varscan2
- DIP2B | c.2111A>G p.Y704C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1355795167, COSV56579205; called by muse, mutect2, varscan2
- EED | c.114T>A p.N38K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV54553255; called by muse, mutect2, varscan2
- EEFSEC | c.577G>C p.A193P | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV54620403; called by muse, mutect2, varscan2
- ESPL1 | c.3907C>A p.P1303T | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57757545; called by muse, mutect2, varscan2
- GALNT2 | c.888C>A p.N296K | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV64193022; called by mutect2, varscan2
- GLIPR1L2 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57553212; called by muse, mutect2, varscan2
- GPR162 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV50589168; called by muse, mutect2, varscan2
- HECW2 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53650312; called by muse, mutect2, varscan2
- HUNK | c.2011A>C p.M671L | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV54224880; called by muse, mutect2, varscan2
- INCENP | c.1819G>A p.D607N (on ENST00000394818 / NM_001040694.2; = p.D603N on NM_020238.3) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs756946965, COSV53913435; called by muse, mutect2, varscan2
- IPO13 | c.1405C>A p.L469I | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT tolerated (0.23); PolyPhen benign (0.205); catalogued as COSV64893834; called by muse, mutect2, varscan2
- ITPR2 | c.2231G>C p.R744P | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101189851, COSV67265059; called by muse, mutect2, varscan2
- KDELR3 | c.328A>G p.N110D | Missense Mutation (SNP) | VAF 161/356 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs1380978597, COSV53246638; called by muse, mutect2, varscan2
- KDM5A | c.4843T>C p.C1615R | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV66990483; called by muse, mutect2, varscan2
- KIAA1549 | c.2921T>G p.I974S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54306255; called by muse, mutect2, varscan2
- LAMP1 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1474931156, COSV60210770; called by muse, mutect2, varscan2
- LYN | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as COSV72922989; called by muse, mutect2, varscan2
- MCM3 | c.1087C>G p.Q363E (on ENST00000229854 / NM_001366374.2; = p.Q353E on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57716631, COSV57716844; called by muse, mutect2, varscan2
- MICAL3 | c.5512A>G p.R1838G | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs753848322, COSV71588055; called by muse, mutect2, varscan2
- MLH1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.038); catalogued as rs63750133, CM046061, COSV51614653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLLT10 | c.2734A>T p.I912F (on ENST00000307729 / NM_001195626.3; = p.I928F on NM_004641.3) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1444769205, COSV56991595, COSV56996371; called by muse, mutect2, varscan2
- MTMR3 | c.1677G>T p.V559= | Splice Region (SNP) | VAF 51/160 reads (32%) | catalogued as COSV60301985; called by muse, mutect2, varscan2
- MUC21 | c.1312T>A p.S438T | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.019); catalogued as COSV66220253; called by muse, mutect2, varscan2
- MZF1 | c.1878C>A p.H626Q | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.37); PolyPhen benign (0.188); catalogued as COSV53040727; called by muse, mutect2, varscan2
- NEMF | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs370101877; called by muse, mutect2, varscan2
- NLRP9 | c.329T>A p.I110K | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV60459925; called by muse, mutect2, varscan2
- POLR2F | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV68091184; called by muse, mutect2, varscan2
- RAD23B | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63657626; called by muse, mutect2, varscan2
- RANBP17 | c.455T>A p.I152K | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV66644892, COSV66648666; called by muse, mutect2, varscan2
- RDH5 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57676010; called by muse, mutect2, varscan2
- RGS7 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58531491; called by muse, mutect2, varscan2
- RRP15 | c.641T>G p.L214W | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65117337; called by muse, mutect2, varscan2
- SAT2 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV52646228; called by muse, mutect2, varscan2
- SEC13 | c.947A>G p.E316G (on ENST00000350697 / NM_183352.3; = p.E319G on NM_030673.4) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV61601279; called by muse, mutect2, varscan2
- SECISBP2 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60527558; called by muse, mutect2, varscan2
- SLC17A4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV64955685; called by muse, mutect2
- SLC25A48 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50848071; called by muse, mutect2, varscan2
- SLC35F2 | c.485T>G p.V162G | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV56182017; called by muse, mutect2, varscan2
- SLC38A3 | c.1471A>G p.I491V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV68843909; called by muse, mutect2, varscan2
- SLC40A1 | c.1349T>A p.V450E | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV53721944; called by muse, mutect2, varscan2
- SLC43A1 | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs116416099, COSV53557634; called by muse, mutect2, varscan2
- SLC6A12 | c.790T>A p.Y264N | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.594); catalogued as COSV62883972; called by muse, mutect2, varscan2
- SRRM2 | c.2277C>G p.S759R | Missense Mutation (SNP) | VAF 166/279 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV57068818; called by muse, mutect2, varscan2
- TIGAR | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51626751; called by muse, mutect2, varscan2
- ZMAT3 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as COSV60992256; called by muse, mutect2, varscan2
- ZNF461 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64452950; called by muse, mutect2, varscan2
- ZNF48 | c.169G>C p.A57P | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV60782445; called by muse, mutect2
- ZNF557 | c.33C>G p.A11= (on ENST00000414706 / NM_001044388.2; = p.A18= on NM_024341.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 47/101 reads (47%) | catalogued as COSV53273024; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.572T>C p.L191S | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58349356; called by muse, mutect2, varscan2
- CHMP3 | c.17del p.K6Rfs*16 | Frame Shift Del (DEL) | VAF 80/225 reads (36%) | called by mutect2, pindel, varscan2
- COL19A1 | c.2268del p.I757Yfs*28 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- DISP2 | c.2774del p.N925Mfs*27 | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | called by mutect2, pindel, varscan2
- DLGAP5 | c.146_147dup p.V50Mfs*2 | Frame Shift Ins (INS) | VAF 25/47 reads (53%) | called by mutect2, pindel, varscan2
- FERD3L | c.340del p.M114Cfs*40 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- HSPA9 | c.416del p.N139Mfs*33 | Frame Shift Del (DEL) | VAF 37/105 reads (35%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.9853del p.W3285Gfs*2 | Frame Shift Del (DEL) | VAF 58/176 reads (33%) | called by mutect2, pindel, varscan2
- MOCS2 | c.370dup p.R124Kfs*26 | Frame Shift Ins (INS) | VAF 72/187 reads (39%) | called by mutect2, pindel, varscan2
- NEIL2 | c.184del p.M62Wfs*82 | Frame Shift Del (DEL) | VAF 80/200 reads (40%) | called by mutect2, pindel, varscan2
- PKD1 | c.7864-13_7864-3del | Splice Region (DEL) | VAF 65/144 reads (45%) | called by mutect2, pindel, varscan2
- RAD54B | c.728del p.N243Ifs*44 | Frame Shift Del (DEL) | VAF 52/122 reads (43%) | called by mutect2, pindel, varscan2
- SEMA3D | c.1862del p.T621Ifs*17 | Frame Shift Del (DEL) | VAF 262/485 reads (54%) | called by mutect2, pindel, varscan2
- SIDT2 | c.1040_1042del p.S347del | In Frame Del (DEL) | VAF 56/138 reads (41%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.946_951del p.L316_D317del | In Frame Del (DEL) | VAF 70/92 reads (76%) | called by mutect2, pindel, varscan2
- TTC3 | c.5277dup p.A1760Cfs*16 | Frame Shift Ins (INS) | VAF 103/301 reads (34%) | called by mutect2, pindel, varscan2
- CPXM1 | c.1254G>C p.L418= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV66044662; called by muse, mutect2, varscan2
- ERCC2 | c.462C>T p.H154= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV55538830; called by muse, mutect2, varscan2
- GEM | c.783C>T p.S261= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV52596662, COSV99891491; called by muse, mutect2, varscan2
- LINGO3 | c.1563G>A p.P521= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs751953704, COSV68260982; called by muse, mutect2, varscan2
- MRO | c.426T>C p.D142= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs1303413992, COSV56494968; called by muse, mutect2
- MYO5A | c.5364A>G p.P1788= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV62556742; called by muse, mutect2, varscan2
- OR13J1 | c.576G>A p.T192= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs747500874, COSV65069352; called by muse, mutect2, varscan2
- PRKCB | c.177C>T p.G59= | Silent (SNP) | VAF 189/321 reads (59%) | catalogued as COSV57767018; called by muse, mutect2, varscan2
- PSTK | c.210A>G p.R70= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV64398195; called by muse, mutect2, varscan2
- RABGAP1 | c.657C>T p.V219= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV58059708; called by muse, mutect2, varscan2
- RYR1 | c.13545C>T p.P4515= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1374723358, COSV62089874, COSV62094454; called by muse, mutect2, varscan2
- SEMA6A | c.849C>T p.C283= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV57307466; called by muse, mutect2, varscan2
- XYLB | c.267C>G p.V89= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs962420781, COSV52911656; called by muse, mutect2, varscan2
- ZC3H18 | c.681C>T p.F227= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs776042272, COSV56322759; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*250C>G | 3'UTR (SNP) | VAF 18/26 reads (69%) | catalogued as COSV70416383; called by muse, mutect2, varscan2
- BAX | c.474+159T>C | Intron (SNP) | VAF 41/87 reads (47%) | catalogued as rs750553916, COSV99509315; called by muse, mutect2, varscan2
- SLC25A48 | c.679+136G>T | Intron (SNP) | VAF 29/58 reads (50%) | catalogued as COSV50848073; called by muse, mutect2, varscan2
